Somatic mutation profile of tumor specimen 0DYJ2G from CCDI case PBCSKB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 7.2 years (2,624 days).
Specimen 0DYJ2G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaaaccdd-87bb-4e9e-8417-a097a8b9d569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYJ1R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea78cd20-d9b0-43c8-bc41-cda2b8a6f9eb

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Intron 4, Nonsense Mutation 2, Splice Site 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 112/252 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519792, COSV52800481, COSV52801581; ClinVar: likely pathogenic; called by muse, varscan2
- DNAH3 | c.10429C>T p.R3477* | Nonsense Mutation (SNP) | VAF 92/224 reads (41%) | catalogued as rs750184108; called by muse, varscan2
- KCNT2 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 162/386 reads (42%) | catalogued as rs528303127, COSV54092992; called by muse, varscan2
- KIF5A | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs759690535, COSV99672841; called by muse, varscan2
- PASK | c.1287C>A p.D429E | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52152397; called by muse, varscan2
- TUBA8 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as rs372238980, COSV57814107; called by muse, varscan2
- DNAJC4 | c.365G>T p.S122I | Missense Mutation (SNP) | VAF 113/522 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- FNDC7 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.05); called by muse, varscan2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 22/225 reads (10%) | called by muse, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 22/220 reads (10%) | called by muse, varscan2
- KCNH8 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 120/301 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SOX11 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, varscan2
- TIMM50 | c.278A>T p.E93V | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, varscan2
- VIRMA | c.2062C>A p.L688I | Missense Mutation (SNP) | VAF 84/571 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, varscan2
- ZFHX4 | c.856T>G p.S286A | Missense Mutation (SNP) | VAF 56/543 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- C2orf16 | c.4296G>A p.T1432= | Silent (SNP) | VAF 102/282 reads (36%) | catalogued as rs758978024, COSV62678255; called by muse, varscan2
- LAMA1 | c.7725G>A p.T2575= | Silent (SNP) | VAF 122/292 reads (42%) | catalogued as rs138095695; called by muse, varscan2
- PCNX1 | c.6471G>A p.S2157= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as rs545153224; called by muse, varscan2
- SBNO2 | c.1038C>T p.G346= | Silent (SNP) | VAF 119/277 reads (43%) | catalogued as rs1455241939; called by muse, varscan2
- TAX1BP1 | c.1788T>C p.N596= | Silent (SNP) | VAF 88/366 reads (24%) | called by muse, varscan2
- VPS16 | c.2250G>A p.K750= | Silent (SNP) | VAF 48/236 reads (20%) | called by muse, varscan2
- C7orf66 | n.182C>T | RNA (SNP) | VAF 196/652 reads (30%) | called by muse, varscan2
- FCRL2 | c.311-21T>C | Intron (SNP) | VAF 48/92 reads (52%) | called by muse, varscan2
- GIMAP5 | c.-6-80G>A | Intron (SNP) | VAF 38/97 reads (39%) | catalogued as rs1211234927; called by muse, varscan2
- LRRC8B | c.*74A>G | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs891944719, COSV58375831; called by muse, varscan2
- MIOS | c.2402-36G>A | Intron (SNP) | VAF 60/164 reads (37%) | called by muse, varscan2
- SLC27A1 | c.997-55C>T | Intron (SNP) | VAF 20/48 reads (42%) | catalogued as COSV53099541; called by muse, varscan2
